Gene-level copy-number profile of tumor specimen TCGA-57-1582-01A from TCGA case TCGA-57-1582, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-57-1582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e9a6932d-2457-47a1-92ef-db2d0c3638e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-57-1582-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/86ccf5a6-adcb-4b24-810d-ac90cc674068

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 835; copy number 2: 5,837; copy number 3: 14,567; copy number 4: 16,804; copy number 5: 11,570; copy number 6: 5,241; copy number 7: 2,156; copy number 8: 1,730; copy number 9: 357; copy number 11: 211; copy number 12: 126; copy number 13: 121; copy number 15: 41; copy number 19: 209.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-57-1582-01): tumor purity 0.82, ploidy 4.08, whole-genome doublings 2 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,065 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:58,306,245–59,754,808, 22 genes, copy number 9: HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1, FAM107A, AC119424.1, FAM3D-AS1, FAM3D, CFAP20DC, CFAP20DC-AS1, AC126121.3, AC138057.1, AC126121.2, AC126121.1, Metazoa_SRP.
- chr3:191,952,349–198,222,513, 187 genes, copy number 9 (broad region; genes not listed).
- chr6:66,710,242–69,389,506, 19 genes, copy number 9: AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3.
- chr8:39,522,976–40,172,612, 15 genes, copy number 9 (within-gene range 7–9): AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:100,683,488–145,066,685, 690 genes, copy number 11–19 (broad region; genes not listed).
- chr10:44,712–3,556,314, 58 genes, copy number 9: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1.
- chr10:28,338,554–28,941,910, 18 genes, copy number 11: ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93.
- chr20:24,237,255–26,251,546, 56 genes, copy number 9: RNU1-23P, AL158090.1, GAPDHP53, SYNDIG1, AL157413.1, AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.

Autosomal genes at a single copy (total copy number 1): 835. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
